Somatic mutation profile of tumor specimen TCGA-WE-A8ZY-06A (aliquot TCGA-WE-A8ZY-06A-11D-A372-08) from TCGA case TCGA-WE-A8ZY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.3 years (23,843 days).
Specimen TCGA-WE-A8ZY-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f254014-0d45-41fe-82f0-00210f770f8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8ZY-10A (Blood Derived Normal), aliquot TCGA-WE-A8ZY-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/891a784f-658d-4d99-872f-b6bdd50168be

The open-access MAF lists 290 somatic variants for this specimen: 182 protein-altering or splice-affecting, 101 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 101, Splice Site 7, Nonsense Mutation 4, 5'Flank 4, Frame Shift Del 3, Intron 2, Splice Region 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 77/167 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 78/177 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 22/47 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2, varscan2
- ABHD15 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV56195032; called by muse, mutect2, varscan2
- ACTG2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.219); catalogued as rs1363649764, COSV100608968; called by muse, mutect2, varscan2
- ACVR1C | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433229241, COSV54646021; called by muse, mutect2, varscan2
- ADAM22 | c.1485G>A p.K495= | Splice Region (SNP) | VAF 25/97 reads (26%) | catalogued as COSV99716346; called by muse, mutect2, varscan2
- ADCY10 | c.3865G>A p.G1289S | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.086); catalogued as rs926879187, COSV100896710; called by muse, mutect2, varscan2
- AGO1 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100940799; called by muse, mutect2, varscan2
- AGO1 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100940800; called by muse, mutect2, varscan2
- APMAP | c.96C>A p.S32R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99468396; called by muse, mutect2, varscan2
- ARHGAP17 | c.2437C>T p.P813S (on ENST00000289968 / NM_001006634.3; = p.P735S on NM_018054.6) | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99253204; called by muse, mutect2, varscan2
- ARMC4 | c.2428A>T p.N810Y | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as COSV100536558; called by muse, mutect2, varscan2
- ARMC6 | c.1273C>T p.P425S (on ENST00000392336; = p.P400S on NM_033415.4) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as COSV99522993; called by muse, mutect2
- AZU1 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99297223; called by muse, mutect2, varscan2
- B3GALT2 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV100813580; called by muse, mutect2, varscan2
- BMP4 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); catalogued as rs565895316, COSV99816843; called by muse, mutect2, varscan2
- BPIFC | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751325586, COSV99322045; called by muse, mutect2, varscan2
- BPIFC | c.517T>G p.S173A | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV100300918; called by muse, varscan2
- BRINP3 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs772531253, COSV66520441; called by muse, mutect2, varscan2
- BRIX1 | c.916G>C p.V306L | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as COSV100331322; called by muse, mutect2, varscan2
- C6 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99666843; called by muse, mutect2, varscan2
- C9orf131 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV100398003; called by muse, mutect2, varscan2
- CACNA2D2 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99817282; called by muse, mutect2
- CACNA2D3 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1203714130, COSV55529890; called by muse, mutect2, varscan2
- CARMIL2 | c.2791G>T p.E931* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100576022; called by muse, mutect2
- CASR | c.1780G>A p.E594K (on ENST00000490131; = p.E671K on NM_000388.4) | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.12); catalogued as COSV56139722; called by muse, mutect2, varscan2
- CCDC170 | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV99498293; called by muse, mutect2, varscan2
- CCDC69 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV62600051; called by muse, mutect2, varscan2
- CCDC71 | c.699C>G p.S233R | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs746920925, COSV100422329; called by muse, mutect2, varscan2
- CCR5 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 243/402 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99433282; called by muse, mutect2, varscan2
- CEP43 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV100835586; called by muse, mutect2, varscan2
- CFAP46 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.691); catalogued as COSV63949649; called by muse, mutect2, varscan2
- CHD4 | c.4075G>A p.E1359K (on ENST00000357008 / NM_001363606.2; = p.E1372K on NM_001273.5) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100537647; called by muse, mutect2, varscan2
- CLEC2B | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99946936; called by muse, mutect2, varscan2
- CLIC2 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs5940668, COSV58936260; called by muse, mutect2, varscan2
- CNTN5 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.486); catalogued as rs1489941088, COSV54278175; called by muse, mutect2, varscan2
- COBL | c.1768C>T p.H590Y | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99472002; called by muse, mutect2, varscan2
- COL14A1 | c.4523C>T p.P1508L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99918625; called by muse, mutect2, varscan2
- COL4A6 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 76/84 reads (90%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100563796, COSV57870594; called by muse, mutect2, varscan2
- CPNE2 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV51962345; called by muse, mutect2, varscan2
- CPNE2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV99321354; called by muse, mutect2, varscan2
- CRTC2 | c.1752T>G p.F584L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.543); catalogued as COSV100338934; called by muse, mutect2, varscan2
- CYP2C18 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV99608400; called by muse, mutect2, varscan2
- CYP2C8 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100987908; called by muse, mutect2, varscan2
- DAB2 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 67/80 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100297887; called by muse, mutect2, varscan2
- DCUN1D5 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99499027; called by muse, mutect2, varscan2
- DEFA4 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.942); catalogued as rs868785648, COSV52404722; called by muse, mutect2, varscan2
- DIP2B | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV99998241; called by muse, mutect2, varscan2
- DKK1 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.481); catalogued as rs200984065, COSV100906520; called by muse, mutect2, varscan2
- DNAH2 | c.6977G>A p.C2326Y | Missense Mutation (SNP) | VAF 50/65 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV101209137; called by muse, mutect2, varscan2
- DNAJB13 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.596); catalogued as rs750950916, COSV60268994; called by muse, mutect2, varscan2
- DOCK3 | c.4067G>A p.R1356Q | Missense Mutation (SNP) | VAF 84/158 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772033575, COSV99810552; called by muse, mutect2, varscan2
- DPPA3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV61503139; called by muse, mutect2, varscan2
- DTL | c.120C>A p.H40Q | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100877175; called by muse, mutect2, varscan2
- EAF1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 188/349 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770331205, COSV101112760; called by muse, mutect2, varscan2
- ECHDC3 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV64867676; called by muse, mutect2, varscan2
- F10 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.132); catalogued as COSV100979179; called by muse, mutect2, varscan2
- F12 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); catalogued as rs1486683301, COSV53692305, COSV99499934; called by muse, mutect2, varscan2
- FAT2 | c.5129G>A p.G1710D | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488047694, COSV55819603; called by muse, mutect2, varscan2
- FBXL16 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.576); catalogued as COSV100178849; called by muse, mutect2, varscan2
- FBXL8 | c.1055C>G p.P352R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99263456; called by muse, mutect2
- FLG2 | c.285A>C p.K95N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV101165752; called by muse, mutect2, varscan2
- FOXR2 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV100189450; called by muse, mutect2, varscan2
- FOXRED2 | c.1667G>A p.R556Q | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs748319420, COSV99340792; called by muse, mutect2, varscan2
- FPR2 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 39/106 reads (37%) | catalogued as COSV100389216, COSV60672761; called by muse, mutect2, varscan2
- GLRA3 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV56868727, COSV99927306; called by muse, mutect2, varscan2
- GPRC6A | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV100114223, COSV100114798; called by muse, mutect2, varscan2
- GRIN2A | c.3311C>A p.T1104N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs755577016, COSV100409241; called by muse, mutect2, varscan2
- GRK2 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV100419617; called by muse, mutect2, varscan2
- GRM2 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs201541353, COSV99622649; called by muse, mutect2, varscan2
- GTF3C6 | c.138+1G>A p.X46_splice | Splice Site (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100328716; called by muse, mutect2, varscan2
- GYS2 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs370887018; called by muse, mutect2, varscan2
- H1-3 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs780578769, COSV55098444; called by muse, mutect2, varscan2
- HADHA | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101023832; called by muse, mutect2, varscan2
- HDAC6 | c.2272G>A p.G758S | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as COSV61930112; called by muse, mutect2, varscan2
- HEATR1 | c.4658C>T p.T1553I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1447897162, COSV100857369, COSV100857579; called by muse, mutect2, varscan2
- HMSD | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs191472221, COSV68816996; called by muse, mutect2, varscan2
- HPSE | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs372465992; called by muse, mutect2, varscan2
- HROB | c.51T>G p.D17E | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99809192; called by muse, mutect2, varscan2
- HYDIN | c.12454G>A p.D4152N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as COSV66636846, COSV66638877; called by muse, mutect2, varscan2
- IFIT1B | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as COSV100879065; called by muse, mutect2, varscan2
- IL17F | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as rs765796484, COSV100277158; called by muse, mutect2, varscan2
- ITGA8 | c.1844A>T p.E615V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV100959070, COSV65235083; called by muse, mutect2, varscan2
- JAML | c.349G>A p.E117K (on ENST00000356289 / NM_001098526.2; = p.E107K on NM_153206.3) | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52626520; called by muse, mutect2, varscan2
- KCNB2 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.856); catalogued as rs768925064, COSV73050505; called by muse, mutect2, varscan2
- KIDINS220 | c.4414C>T p.P1472S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.146); catalogued as COSV99875381; called by muse, mutect2, varscan2
- LCMT2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV59790996; called by muse, mutect2, varscan2
- LPIN3 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV64718745; called by muse, mutect2, varscan2
- LRBA | c.6779T>A p.L2260H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100841241; called by muse, mutect2, varscan2
- LRFN2 | c.1598C>T p.T533I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599347; called by muse, mutect2, varscan2
- LRIG1 | c.2153G>A p.G718E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99833492; called by muse, mutect2, varscan2
- LRRC17 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV99978306; called by muse, mutect2, varscan2
- LY9 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99626487; called by muse, mutect2, varscan2
- MANEA | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100721479; called by muse, mutect2, varscan2
- MED14 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs1263698610, COSV100247406; called by muse, mutect2, varscan2
- MGAM | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV72075019; called by muse, mutect2, varscan2
- MGAM | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs777169037, COSV72074491; called by muse, mutect2, varscan2
- MGST1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778251722, COSV99163161; called by muse, mutect2, varscan2
- MRGPRX4 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.042); catalogued as COSV100049691; called by muse, mutect2, varscan2
- MYT1L | c.2530C>A p.P844T | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.913); catalogued as rs539249633, COSV101219819; called by muse, mutect2, varscan2
- NCAN | c.2273C>T p.S758F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99386938; called by muse, mutect2, varscan2
- NES | c.4724G>A p.R1575Q | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs745594506, COSV100957819; called by muse, mutect2, varscan2
- NPC1 | c.1948-2A>C p.X650_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV52577424, COSV99341091; called by muse, mutect2, varscan2
- NPHS1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.16); catalogued as COSV100799706; called by muse, mutect2, varscan2
- NRXN1 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV100454241, COSV58463917; called by muse, mutect2, varscan2
- NRXN3 | c.1486G>A p.D496N (on ENST00000335750 / NM_001330195.2; = p.D123N on NM_004796.6) | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV59786887; called by muse, mutect2, varscan2
- NUCB2 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs1434175130, COSV100082669; called by muse, mutect2, varscan2
- NUTM2D | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs1435628332, COSV67745981, COSV67746448; called by muse, mutect2, varscan2
- OR4K15 | c.145C>A p.P49T (on ENST00000305051; = p.P25T on NM_001005486.1) | Missense Mutation (SNP) | VAF 78/103 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1180214334, COSV100521012; called by muse, mutect2, varscan2
- OR6K3 | c.247T>A p.S83T (on ENST00000368146; = p.S67T on NM_001005327.2) | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100933844; called by muse, mutect2, varscan2
- PALMD | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763111291, COSV99586253; called by muse, mutect2, varscan2
- PCLO | c.10903G>A p.A3635T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as COSV61616958; called by muse, mutect2, varscan2
- PEG3 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV55626356, COSV99687015; called by muse, mutect2, varscan2
- PIK3C2A | c.4015C>T p.P1339S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99790487; called by muse, mutect2
- PKHD1L1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as rs1159235756, COSV65742447; called by muse, mutect2
- PLCB4 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); catalogued as rs770376711, COSV99594938; called by muse, mutect2, varscan2
- PLCB4 | c.2551C>A p.Q851K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.562); catalogued as COSV99594940; called by muse, mutect2, varscan2
- PLCE1 | c.2421-1G>A p.X807_splice | Splice Site (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99594325; called by muse, mutect2, varscan2
- PLEKHS1 | c.762-1G>A p.X254_splice (on ENST00000369310 / NM_182601.1; = p.X260_splice on NM_024889.5) | Splice Site (SNP) | VAF 30/70 reads (43%) | catalogued as rs986197735, COSV100613044; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as rs377599210; called by muse, mutect2, varscan2
- PPM1K | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.788); catalogued as rs753095031, COSV55797566; called by muse, mutect2, varscan2
- PRAMEF20 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as rs1299707271, COSV100326322; called by muse, mutect2, varscan2
- PRPF38B | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100898239; called by muse, mutect2, varscan2
- PTCHD3 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs1475095285, COSV71256265; called by muse, mutect2, varscan2
- PZP | c.3775G>A p.D1259N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99737161; called by muse, mutect2, varscan2
- PZP | c.3775-1G>A p.X1259_splice | Splice Site (SNP) | VAF 17/51 reads (33%) | catalogued as rs1052959241, COSV99735872; called by muse, mutect2, varscan2
- RAG1 | c.2239C>T p.H747Y | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100200791; called by muse, mutect2, varscan2
- RASA3 | c.1700G>A p.R567K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100480252; called by muse, mutect2, varscan2
- RBM46 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99908000; called by muse, mutect2, varscan2
- RGS5 | c.326T>C p.M109T | Missense Mutation (SNP) | VAF 150/337 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV100008950; called by muse, mutect2, varscan2
- ROBO2 | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV100165516; called by muse, mutect2, varscan2
- SACS | c.6277C>T p.R2093C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1305578930, COSV101207293; called by muse, mutect2, varscan2
- SCGN | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as COSV100618689; called by muse, mutect2, varscan2
- SCN2A | c.3572G>A p.G1191E | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99330890; called by muse, mutect2, varscan2
- SEMA4A | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1254471376, COSV61774160; called by muse, mutect2, varscan2
- SERPINB12 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); catalogued as rs1215216355, COSV99501560; called by muse, mutect2, varscan2
- SETD2 | c.4044T>G p.H1348Q | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100338587; called by muse, mutect2, varscan2
- SLC6A15 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 70/88 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs772296811, COSV57019493; called by muse, mutect2, varscan2
- SLITRK1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.068); catalogued as rs1196654231, COSV65675702; called by muse, mutect2, varscan2
- SPEF2 | c.1900-1G>A p.X634_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100606870; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100561681; called by muse, mutect2, varscan2
- SULT1C3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as COSV100227398; called by muse, mutect2, varscan2
- SVOPL | c.790G>A p.E264K (on ENST00000419765; = p.E112K on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV55990683; called by muse, mutect2, varscan2
- TANC1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99713449; called by muse, mutect2, varscan2
- TAS2R7 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs760804047, COSV99553690; called by muse, mutect2, varscan2
- TECTB | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs192144192, COSV65596269; called by muse, mutect2, varscan2
- TECTB | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65596018; called by muse, mutect2, varscan2
- TG | c.749T>C p.L250S | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99599973; called by muse, mutect2, varscan2
- TIAM2 | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100018471; called by muse, mutect2, varscan2
- TJP3 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs202057643, COSV53663747; called by muse, mutect2, varscan2
- TLDC2 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99455821; called by muse, mutect2, varscan2
- TLL1 | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99286769; called by muse, mutect2, varscan2
- TLL2 | c.2448+1G>A p.X816_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as rs753694722, COSV100780215; called by muse, mutect2, varscan2
- TMCC3 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.23); PolyPhen benign (0.282); catalogued as COSV99705351; called by muse, mutect2, varscan2
- TMCO5A | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1159665366, COSV60465762; called by muse, mutect2, varscan2
- TMEM132D | c.1497G>C p.K499N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV101242687; called by muse, mutect2, varscan2
- TMEM200A | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.945); catalogued as COSV51650171; called by muse, mutect2, varscan2
- TP63 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.96); PolyPhen benign (0.443); catalogued as COSV99286329; called by muse, mutect2, varscan2
- TRIM58 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV63570010, COSV63572091; called by muse, mutect2, varscan2
- TRPS1 | c.1750C>T p.P584S (on ENST00000220888 / NM_001330599.2; = p.P597S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV55237479, COSV55254966; called by muse, mutect2, varscan2
- TSSK6 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1474112015, COSV99388997; called by muse, mutect2, varscan2
- TTN | c.38947G>A p.E12983K (on ENST00000591111; = p.E5559K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | PolyPhen possibly damaging (0.616); catalogued as COSV59927228; called by muse, mutect2, varscan2
- TTN | c.24538C>T p.R8180C (on ENST00000591111; = p.R7253C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | PolyPhen possibly damaging (0.867); catalogued as rs369517119, COSV60243203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.11491C>T p.P3831S (on ENST00000591111; = p.P3785S on NM_003319.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as rs1340668784, COSV59930330; called by muse, mutect2, varscan2
- U2SURP | c.2852C>T p.S951L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1186177225, COSV67530201; called by muse, mutect2, varscan2
- UHRF1 | c.538G>A p.E180K (on ENST00000612630 / NM_001290050.1; = p.E193K on NM_013282.4) | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.7); catalogued as COSV53573140, COSV53573972; called by muse, mutect2, varscan2
- UNC13B | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 88/104 reads (85%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.11); catalogued as COSV101036485; called by muse, mutect2, varscan2
- UNC13C | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52899158; called by muse, mutect2, varscan2
- UNC5D | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773478021, COSV54776215, COSV99771084; called by muse, mutect2, varscan2
- VWF | c.6817C>T p.P2273S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV99778562; called by muse, mutect2, varscan2
- XBP1 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1041238756, COSV99321598; called by muse, mutect2, varscan2
- ZBTB41 | c.1291C>T p.H431Y | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs1301159692, COSV100962992; called by muse, mutect2, varscan2
- ZDHHC2 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs865781578, COSV50497411; called by muse, mutect2, varscan2
- ZNF229 | c.2104C>T p.H702Y | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99350267; called by muse, mutect2, varscan2
- ZNF35 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs761598072, COSV99940013; called by muse, mutect2, varscan2
- ZNF443 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100042035; called by muse, mutect2, varscan2
- ZNF761 | c.1798C>T p.H600Y | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV61887977; called by muse, mutect2, varscan2
- GABRG1 | c.340del p.I114Ffs*11 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- POTEA | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TOPORS | c.1249del p.D417Mfs*23 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | called by mutect2, pindel, varscan2
- VNN2 | c.277_278del p.V93Ffs*54 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1761C>T p.S587= | Silent (SNP) | VAF 38/129 reads (29%) | catalogued as COSV100228715; called by muse, mutect2, varscan2
- ABCC6 | c.2616G>A p.K872= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99228460; called by muse, mutect2, varscan2
- ABCF3 | c.1137C>T p.V379= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs367881517, COSV53052501; called by muse, mutect2, varscan2
- ACTG2 | c.1086G>A p.E362= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100608971; called by muse, mutect2, varscan2
- ANKRD12 | c.2190C>T p.I730= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV100041024; called by muse, mutect2, varscan2
- AQP8 | c.120C>T p.V40= | Silent (SNP) | VAF 49/214 reads (23%) | catalogued as rs371151656, COSV54847208; called by muse, mutect2, varscan2
- ARID5A | c.1473C>T p.A491= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV100673555; called by muse, mutect2, varscan2
- ARL3 | c.66C>T p.L22= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs777881668, COSV99589001; called by muse, mutect2, varscan2
- ASPG | c.613C>T p.L205= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs373844611, COSV101496372; called by muse, varscan2
- B3GALT2 | c.1068A>G p.V356= | Silent (SNP) | VAF 56/106 reads (53%) | catalogued as COSV66464140; called by muse, mutect2, varscan2
- BDKRB1 | c.750G>A p.A250= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs374961307; called by muse, mutect2, varscan2
- BPI | c.1374C>T p.L458= (on ENST00000262865; = p.L454= on NM_001725.3) | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as COSV99480515; called by muse, mutect2, varscan2
- BPIFB2 | c.1365C>T p.F455= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs1265678073, COSV50072080, COSV99401301; called by muse, mutect2, varscan2
- C20orf96 | c.990C>T p.P330= (on ENST00000360321 / NM_153269.3; = p.P329= on NM_080571.1) | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as COSV100826682; called by muse, mutect2, varscan2
- CBY2 | c.390C>T p.F130= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV100137547; called by muse, mutect2, varscan2
- CD163L1 | c.3108C>T p.L1036= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs938129839, COSV100549902; called by muse, mutect2, varscan2
- CD2 | c.711G>A p.R237= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs1557918878, COSV65643852; called by muse, mutect2, varscan2
- CEP89 | c.2196C>T p.I732= | Silent (SNP) | VAF 68/187 reads (36%) | catalogued as COSV99993298; called by muse, mutect2, varscan2
- CHD8 | c.630C>T p.P210= | Silent (SNP) | VAF 24/29 reads (83%) | catalogued as COSV101303080; called by muse, mutect2, varscan2
- CLEC16A | c.2686C>T p.L896= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs1351462345, COSV99901316; called by muse, mutect2, varscan2
- CSAD | c.360C>T p.I120= (on ENST00000444623 / NM_001244705.2; = p.I147= on NM_015989.5) | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as rs764495154, COSV99914621; called by muse, mutect2, varscan2
- CSMD2 | c.7524C>T p.I2508= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs1219542800, COSV99588153; called by muse, mutect2, varscan2
- CTNNA3 | c.171C>T p.V57= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV100373440, COSV57720083; called by muse, mutect2, varscan2
- CYBB | c.450A>G p.E150= | Silent (SNP) | VAF 41/48 reads (85%) | catalogued as CD105711, COSV101059724; called by muse, mutect2, varscan2
- DHX37 | c.1917G>A p.G639= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV58131517; called by muse, mutect2, varscan2
- DSP | c.3957C>T p.T1319= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as COSV101131215; called by muse, mutect2, varscan2
- DSP | c.5826C>T p.L1942= | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as COSV101131216, COSV65796560; called by muse, mutect2, varscan2
- EPHA5 | c.2415C>T p.N805= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99897780; called by muse, mutect2, varscan2
- EPO | c.525C>T p.F175= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV53161577; called by muse, mutect2, varscan2
- FOXRED2 | c.1668G>A p.R556= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV99340790; called by muse, mutect2, varscan2
- GAD1 | c.132G>A p.G44= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100713790; called by mutect2, varscan2
- GON4L | c.4218G>A p.V1406= | Silent (SNP) | VAF 48/78 reads (62%) | catalogued as COSV99673883; called by muse, mutect2, varscan2
- GOT2 | c.795C>T p.I265= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1473050414, COSV55331727; called by muse, mutect2, varscan2
- GPR15 | c.927C>T p.I309= | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as COSV99423691; called by muse, varscan2
- H1-3 | c.360G>A p.K120= | Silent (SNP) | VAF 61/109 reads (56%) | catalogued as rs749696539, COSV99768691; called by muse, mutect2, varscan2
- HDAC6 | c.2271G>A p.E757= | Silent (SNP) | VAF 42/49 reads (86%) | catalogued as rs148707580, COSV100490699; called by muse, mutect2, varscan2
- HDHD5 | c.690C>T p.L230= (on ENST00000336737 / NM_033070.3; = p.L200= on NM_017829.5) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1217329983, COSV99324617; called by muse, mutect2, varscan2
- HYDIN | c.14623C>T p.L4875= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs756752724, COSV101125001; called by muse, mutect2, varscan2
- IL31 | c.486C>T p.A162= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as COSV100986562; called by muse, mutect2, varscan2
- IMPG1 | c.909A>G p.Q303= | Silent (SNP) | VAF 47/69 reads (68%) | catalogued as COSV100886289; called by muse, mutect2, varscan2
- KCNG1 | c.1359C>G p.A453= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100857048; called by muse, mutect2, varscan2
- KCNMA1 | c.1494G>A p.P498= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs760119167, COSV99694192, COSV99696201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1755 | c.261A>G p.E87= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV99641776; called by muse, mutect2, varscan2
- KIR3DL2 | c.400C>T p.L134= | Silent (SNP) | VAF 105/333 reads (32%) | called by muse, mutect2, varscan2
- KLHL17 | c.1140C>T p.A380= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100497940; called by muse, mutect2, varscan2
- KLHL6 | c.1437G>A p.G479= | Silent (SNP) | VAF 72/123 reads (59%) | catalogued as COSV100384481; called by muse, mutect2, varscan2
- KRT81 | c.687G>A p.V229= | Silent (SNP) | VAF 65/80 reads (81%) | catalogued as COSV100576958; called by muse, mutect2, varscan2
- LAMA5 | c.1743C>T p.F581= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99439018; called by muse, mutect2
- LENG8 | c.1758C>T p.V586= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as rs142424676, COSV58725840, COSV58729500; called by muse, mutect2, varscan2
- LMO7 | c.4101G>A p.E1367= (on ENST00000357063; = p.E1048= on NM_005358.5) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100412831; called by muse, mutect2, varscan2
- LOXL2 | c.1923G>T p.L641= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV101207825; called by muse, mutect2, varscan2
- LYST | c.8838A>C p.S2946= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV101088870; called by muse, mutect2, varscan2
- MAP3K15 | c.873C>T p.S291= | Silent (SNP) | VAF 42/49 reads (86%) | catalogued as rs1488042242, COSV100134455; called by muse, mutect2, varscan2
- MIA2 | c.2310C>T p.F770= | Silent (SNP) | VAF 46/69 reads (67%) | catalogued as rs529369922, COSV54490213, COSV99697265; called by muse, mutect2, varscan2
- MOGAT2 | c.855G>A p.G285= | Silent (SNP) | VAF 31/35 reads (89%) | catalogued as rs1316893386, COSV99549461; called by muse, mutect2, varscan2
- MRTFA | c.1107C>T p.F369= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100843945; called by muse, mutect2, varscan2
- MYLK | c.2112C>T p.V704= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV100658782; called by muse, mutect2, varscan2
- NKAPL | c.597G>A p.R199= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100642485; called by muse, mutect2, varscan2
- NOS1AP | c.471C>T p.I157= | Silent (SNP) | VAF 69/130 reads (53%) | catalogued as rs756770777, COSV62632805; called by muse, mutect2, varscan2
- NPHS1 | c.1278G>A p.K426= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100799708; called by muse, mutect2, varscan2
- NUDT12 | c.948C>T p.T316= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100048089; called by muse, mutect2, varscan2
- NUTM2D | c.381G>T p.G127= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV101096889; called by muse, mutect2, varscan2
- OR2B6 | c.942A>G p.*314= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as rs1181310073, COSV99773673; called by muse, mutect2, varscan2
- OR2S2 | c.621C>T p.F207= | Silent (SNP) | VAF 44/54 reads (81%) | catalogued as COSV100558515; called by muse, mutect2, varscan2
- PADI4 | c.1416G>A p.V472= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV100966739; called by muse, mutect2, varscan2
- PASD1 | c.1185C>T p.I395= | Silent (SNP) | VAF 70/77 reads (91%) | catalogued as COSV100949236; called by muse, mutect2, varscan2
- PCDHA13 | c.690C>T p.I230= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV99165551; called by muse, mutect2, varscan2
- PHLDB2 | c.1143G>A p.R381= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV67314516; called by muse, mutect2, varscan2
- PLA1A | c.1083C>T p.F361= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99845771; called by muse, mutect2, varscan2
- PLA2G4F | c.2289C>T p.F763= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV51829075; called by muse, mutect2, varscan2
- PLEKHG4B | c.1221G>A p.L407= (on ENST00000283426; = p.L763= on NM_052909.5) | Silent (SNP) | VAF 33/38 reads (87%) | catalogued as rs1409264440, COSV99360054; called by muse, mutect2, varscan2
- POLE | c.3237C>T p.I1079= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV100265915; called by muse, mutect2, varscan2
- POTEA | c.357G>A p.L119= | Silent (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1215C>T p.L405= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs1347376401, COSV100436180; called by muse, mutect2, varscan2
- PRAMEF15 | c.600C>T p.I200= | Silent (SNP) | VAF 34/219 reads (16%) | called by muse, mutect2, varscan2
- RAI2 | c.141G>A p.K47= | Silent (SNP) | VAF 68/82 reads (83%) | catalogued as rs1190068419, COSV100518240; called by muse, mutect2, varscan2
- RHOBTB2 | c.1015C>T p.L339= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1431019051, COSV99310835; called by muse, mutect2, varscan2
- SCN2A | c.3573G>A p.G1191= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs267598962, COSV51838673; called by muse, mutect2, varscan2
- SFXN4 | c.612C>T p.F204= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1331539146, COSV100341025; called by muse, mutect2, varscan2
- SH2D3C | c.1233C>T p.S411= (on ENST00000314830 / NM_170600.3; = p.S254= on NM_005489.4) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs761676058, COSV100136669, COSV100136875; called by muse, mutect2, varscan2
- SIPA1L3 | c.4098C>T p.A1366= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1453763628, COSV99728061; called by muse, mutect2, varscan2
- SIX5 | c.855G>A p.E285= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs764868951, COSV99352948, COSV99353622; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC38A9 | c.981C>T p.F327= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1222968705, COSV100591333; called by muse, mutect2, varscan2
- STAB2 | c.463T>C p.L155= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV101185785; called by muse, mutect2, varscan2
- STARD5 | c.90C>T p.C30= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs781744902, COSV100250792, COSV57154964; called by muse, mutect2, varscan2
- TAS2R14 | c.795C>T p.S265= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV101113946; called by muse, mutect2, varscan2
- TENM4 | c.5754C>T p.F1918= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as rs1406976860, COSV53614946; called by muse, mutect2, varscan2
- TFAP4 | c.816C>T p.I272= | Silent (SNP) | VAF 52/98 reads (53%) | catalogued as rs201856455, COSV52597627; called by muse, mutect2, varscan2
- TIGD5 | c.459C>A p.A153= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100363985; called by muse, mutect2
- TKTL2 | c.1350C>T p.F450= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV54917401, COSV54922345, COSV99761327; called by muse, mutect2, varscan2
- TMEM150C | c.39T>C p.P13= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV101496904; called by muse, mutect2, varscan2
- TNFRSF11B | c.810C>T p.I270= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV52072007, COSV99816535; called by muse, mutect2, varscan2
- TNNI1 | c.552G>A p.P184= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs755922548, COSV60189059; called by muse, mutect2, varscan2
- TTBK2 | c.3060C>T p.L1020= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs55735086; called by muse, mutect2, varscan2
- UBE4B | c.3265C>T p.L1089= (on ENST00000343090 / NM_001105562.3; = p.L960= on NM_006048.5) | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV53543566; called by muse, mutect2, varscan2
- WDR77 | c.129C>A p.L43= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs1208286166, COSV99330766; called by muse, mutect2, varscan2
- WNT3A | c.300C>T p.P100= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs767871879, COSV52729744; called by muse, mutect2, varscan2
- ZBED6CL | c.9C>T p.V3= | Silent (SNP) | VAF 54/103 reads (52%) | catalogued as COSV100550426; called by muse, mutect2, varscan2
- ZNF106 | c.4503C>T p.S1501= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs952141618, COSV99782392; called by muse, mutect2, varscan2
- ZNF438 | c.1599C>T p.R533= | Silent (SNP) | VAF 61/161 reads (38%) | catalogued as COSV100061573; called by muse, mutect2, varscan2
- ZNF486 | c.546G>A p.L182= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as rs781937690, COSV100631170; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504219 G>A | 5'Flank (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457326 G>A | 5'Flank (SNP) | VAF 4/24 reads (17%) | catalogued as rs1402093696; called by mutect2, varscan2
- LINC00173 | n.965C>A | RNA (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604688 G>A | 5'Flank (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- PDE4A | chr19:10417841 C>T | 5'Flank (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100764067; called by muse, mutect2, varscan2
- PRKCB | c.1864-5275G>A | Intron (SNP) | VAF 26/63 reads (41%) | catalogued as rs1165512847, COSV57777227; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44459G>A | Intron (SNP) | VAF 25/98 reads (26%) | catalogued as COSV101043405; called by muse, mutect2, varscan2
